Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A928, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A928-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma, papillary NOS
8260/3
Site Body & stomach
C16.2
4/23/18/14

PRIMARY SITE: Stomach (Body)

Free of neoplasia in the examined sections.

- Moderately differentiated papillary adenocarcinoma (intestinal type of Laurén), infiltrating subserosal adipose tissue;
- maximum dimension of tumor: 7.8 cm;
- angiolymphatic invasion: present;
- perineural invasion: not detected;
- surgical margins: free of neoplasia.

Free of neoplasia (0/1).

Right paracardic: free of neoplasia (0/2).

Greater curvature: fibrous connective tissue and adipose tissue free of neoplasia.

Supra-pyloric: compromised by neoplasia (9/11).

Infra-pyloric: compromised by neoplasia (4/15). Presence of metastatic lymph node conglomerate.

Left gastric artery: compromised by neoplasia (2/5).

Common hepatic artery: compromised by neoplasia (11/18). Presence of metastatic lymph node conglomerate.

Celiac trunk: compromised by neoplasia (6/28).

Splenic artery: free of tumor (0/1).

Category	Yes	No
Is this a true emergency?		☒
Is this a matter of discretion?		☒
Is this a true emergency?		☒
Is this a matter of discretion?		☒
Is this a true emergency?		☒
Is this a matter of discretion?		☒
Is this a true emergency?		☒
Is this a matter of discretion?		☒

Source: NCI Genomic Data Commons file 05524627-b07e-48f4-a4c5-69a675d30185 (TCGA-VQ-A928.8D170BC0-6129-4632-BCCB-F8F5EBC97ABE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).